Somatic mutation profile of tumor specimen ALCH-B3K0-TTP1-A (aliquot ALCH-B3K0-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3K0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.0 years (25,554 days).
Specimen ALCH-B3K0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e2d0c54-5790-41c3-a051-34853ae9efe9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3K0-NB1-A (Blood Derived Normal), aliquot ALCH-B3K0-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59fbfdc1-cdcb-4447-9f51-6bfe1d39a58f

The open-access MAF lists 984 somatic variants for this specimen: 664 protein-altering or splice-affecting, 212 silent, 108 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 560, Silent 212, Nonsense Mutation 50, Intron 39, RNA 38, Frame Shift Del 24, Splice Site 19, 3'UTR 12, 5'UTR 9, 5'Flank 7, Frame Shift Ins 6, 3'Flank 3.

Variants (750 of 984; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A5 | c.385-1G>C p.X129_splice | Splice Site (SNP) | VAF 91/368 reads (25%) | catalogued as rs104886395, CS012493, CS129398; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 90/357 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.2335C>A p.Q779K (on ENST00000404938 / NM_001163941.2; = p.Q334K on NM_178559.6) | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51718861; called by muse, mutect2, varscan2
- ADAMTS12 | c.2684C>A p.S895* | Nonsense Mutation (SNP) | VAF 234/399 reads (59%) | catalogued as COSV100711384, COSV61255573; called by muse, mutect2, varscan2
- ADCY8 | c.2878G>T p.A960S | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53919132; called by muse, mutect2, varscan2
- ADGRB3 | c.4446C>A p.Y1482* | Nonsense Mutation (SNP) | VAF 52/256 reads (20%) | catalogued as COSV53246279; called by muse, mutect2, varscan2
- AGAP6 | c.491C>G p.P164R (on ENST00000374056 / NM_001365867.1; = p.P187R on NM_001077665.2) | Missense Mutation (SNP) | VAF 50/437 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV65017313; called by muse, mutect2, varscan2
- AHDC1 | c.2765C>T p.P922L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1227039585; called by muse, mutect2, varscan2
- AKAP4 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV62074551; called by muse, mutect2, varscan2
- ALG11 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 104/471 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs1283781232; called by muse, mutect2, varscan2
- ALK | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV66568938; called by muse, mutect2, varscan2
- ALS2CL | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.492); catalogued as rs747409127, COSV100014614; called by muse, mutect2, varscan2
- ANKRD26 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs915457685; called by muse, mutect2, varscan2
- AP3B1 | c.3157G>T p.G1053W | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs546653512; called by muse, mutect2, varscan2
- AQP11 | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.876); catalogued as COSV57993239; called by muse, mutect2
- B2M | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 31/246 reads (13%) | catalogued as COSV62563917; called by muse, varscan2
- BAP1 | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56231441; called by muse, mutect2, varscan2
- BEST3 | c.449G>T p.R150I | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56996207; called by muse, mutect2, varscan2
- BMPR1A | c.736G>T p.G246* | Nonsense Mutation (SNP) | VAF 61/415 reads (15%) | catalogued as COSV100923444, COSV64406339; called by muse, mutect2, varscan2
- C1orf141 | c.893A>T p.K298M | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63992973; called by muse, mutect2, varscan2
- C6orf15 | c.626G>T p.W209L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV99457008; called by muse, mutect2, varscan2
- CACNG8 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); catalogued as COSV54416961; called by muse, mutect2, varscan2
- CALD1 | c.1715G>A p.R572K (on ENST00000361675 / NM_033138.4; = p.R317K on NM_004342.7) | Missense Mutation (SNP) | VAF 90/341 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs200216400; called by muse, mutect2, varscan2
- CASK | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 14/354 reads (4%) | catalogued as COSV59374113; called by muse, mutect2
- CASS4 | c.2239G>C p.V747L | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64387906; called by muse, mutect2, varscan2
- CAVIN3 | c.41C>G p.A14G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.19); catalogued as COSV58268796; called by muse, mutect2, varscan2
- CCDC168 | c.6333G>T p.E2111D | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as rs1456152531, COSV101468997; called by muse, mutect2, varscan2
- CCNK | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as rs1322405212; called by muse, mutect2, varscan2
- CCR3 | c.835C>A p.L279M | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV62466066; called by muse, mutect2, varscan2
- CDH12 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 54/358 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV101202955; called by muse, mutect2, varscan2
- CLC | c.194A>C p.N65T | Missense Mutation (SNP) | VAF 35/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs77318783; called by muse, mutect2
- CLEC12A | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs775966618, COSV58562630; called by muse, mutect2, varscan2
- CLIP1 | c.1715C>T p.S572F (on ENST00000620786 / NM_001247997.1; = p.S561F on NM_002956.2) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100211636, COSV56803275, COSV56805181; called by muse, mutect2, varscan2
- CMAS | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs755025797; called by muse, mutect2, varscan2
- CNTNAP2 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 73/406 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771028883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs747922335, COSV62158230, COSV99080851; called by muse, mutect2, varscan2
- COL4A5 | c.3334C>A p.P1112T | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV100089232; called by muse, mutect2, varscan2
- COL5A2 | c.3590G>T p.G1197V | Missense Mutation (SNP) | VAF 119/396 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66412898; called by muse, mutect2, varscan2
- CSMD3 | c.5188G>A p.G1730S (on ENST00000297405 / NM_001363185.1; = p.G1626S on NM_052900.3) | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52095671; called by muse, mutect2, varscan2
- CSMD3 | c.3466C>T p.Q1156* (on ENST00000297405 / NM_001363185.1; = p.Q1052* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 24/569 reads (4%) | catalogued as COSV99842971; called by muse, mutect2
- CTNNB1 | c.2224C>T p.H742Y | Missense Mutation (SNP) | VAF 83/417 reads (20%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.042); catalogued as COSV62696345; called by muse, mutect2, varscan2
- CTNND2 | c.2887G>A p.V963I | Missense Mutation (SNP) | VAF 422/906 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781743390; called by muse, varscan2
- DACH2 | c.1652C>A p.T551N | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.445); catalogued as rs1455800239; called by muse, mutect2, varscan2
- DBH | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs774430399; called by muse, mutect2, varscan2
- DBX2 | c.435del p.P146Hfs*30 | Frame Shift Del (DEL) | VAF 38/242 reads (16%) | catalogued as COSV60336068; called by mutect2, pindel, varscan2
- DCAF4L2 | c.545T>A p.I182N | Missense Mutation (SNP) | VAF 71/399 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1247033527, COSV60476627; called by muse, mutect2, varscan2
- DDX11 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 85/512 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as rs756991541; called by muse, mutect2, varscan2
- DEFB110 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as rs781532241; called by muse, mutect2, varscan2
- DENND2A | c.2009G>T p.R670L | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs562738531, COSV52053144; called by muse, mutect2, varscan2
- DHDH | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as rs751415494; called by muse, varscan2
- DHX37 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.219); catalogued as rs1250041457; called by muse, mutect2
- DLGAP2 | c.2564C>A p.T855K | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.255); catalogued as COSV70104245; called by muse, mutect2, varscan2
- DLGAP3 | c.2410del p.A804Qfs*83 | Frame Shift Del (DEL) | VAF 43/203 reads (21%) | catalogued as COSV99333419; called by mutect2, pindel, varscan2
- DLGAP3 | c.1231G>T p.G411C | Missense Mutation (SNP) | VAF 45/406 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs146586197, COSV52392098, COSV99331996; called by muse, mutect2, varscan2
- DMTN | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs781626631, COSV99741527; called by muse, mutect2, varscan2
- DRD2 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV60762043; called by muse, mutect2, varscan2
- DSCAML1 | c.4509C>A p.D1503E (on ENST00000321322; = p.D1443E on NM_020693.4) | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58398174; called by muse, mutect2, varscan2
- DYTN | c.1456G>T p.G486* | Nonsense Mutation (SNP) | VAF 129/445 reads (29%) | catalogued as COSV71751425; called by muse, mutect2, varscan2
- E2F8 | c.1483G>T p.G495* | Nonsense Mutation (SNP) | VAF 19/94 reads (20%) | catalogued as COSV100001783; called by muse, mutect2, varscan2
- ECM2 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99061777; called by muse, mutect2, varscan2
- ELAVL4 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 8/245 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63914145, COSV63917460; called by muse, mutect2
- EPB41L3 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV59454072; called by muse, mutect2, varscan2
- EPHA8 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs767316353, COSV99386084; called by muse, mutect2, varscan2
- FAT1 | c.9375C>G p.F3125L | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV101499404, COSV71671629; called by muse, mutect2
- FBXO11 | c.2556-1G>C p.X852_splice (on ENST00000403359 / NM_001190274.2; = p.X768_splice on NM_025133.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as COSV52284867; called by muse, mutect2, varscan2
- FGD5 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs767984289, COSV53243707; called by muse, mutect2, varscan2
- FGD5 | c.2971G>A p.A991T | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs539351974, COSV53248570; called by muse, mutect2, varscan2
- FOXM1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs781264755; called by mutect2, varscan2
- FSIP2 | c.19781G>T p.R6594L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100555803; called by muse, mutect2, varscan2
- FZD10 | c.437T>A p.L146Q | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1373396114; called by muse, mutect2, varscan2
- GALNTL6 | c.739A>T p.N247Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV101560226; called by muse, mutect2, varscan2
- GFRA1 | c.1152G>C p.E384D | Missense Mutation (SNP) | VAF 13/329 reads (4%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100815462; called by muse, mutect2
- GLB1 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 58/289 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1553612598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR153 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1233788688, COSV64938301; called by muse, mutect2, varscan2
- GRIN2A | c.2663C>T p.T888M | Missense Mutation (SNP) | VAF 42/354 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149698593, COSV58018962; called by muse, varscan2
- GRIN3A | c.2090G>A p.W697* | Nonsense Mutation (SNP) | VAF 20/352 reads (6%) | catalogued as COSV62458184; called by muse, mutect2
- GRM5 | c.1732C>A p.P578T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.815); catalogued as COSV59633426; called by muse, mutect2, varscan2
- GRM8 | c.2302A>G p.I768V | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.262); catalogued as rs770272411; called by muse, mutect2, varscan2
- GRM8 | c.2138G>T p.W713L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1166614171, COSV58861085; called by muse, mutect2, varscan2
- GTSF1L | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV65932424; called by muse, mutect2, varscan2
- H2BC9 | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as COSV99769319; called by muse, mutect2
- HCFC2 | c.992G>T p.S331I | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57558803; called by muse, mutect2, varscan2
- HECW1 | c.4562G>A p.R1521H | Missense Mutation (SNP) | VAF 76/398 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs756422420, COSV67837695; called by muse, mutect2, varscan2
- HEG1 | c.2171C>A p.T724K | Missense Mutation (SNP) | VAF 95/499 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV60761185; called by muse, mutect2, varscan2
- HLA-C | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66110130; called by muse, mutect2, varscan2
- HRNR | c.2416C>A p.H806N | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as rs1284854242, COSV64257649; called by muse, mutect2
- HSPG2 | c.6131C>T p.S2044L | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV101021042; called by muse, varscan2
- IFT74 | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 26/146 reads (18%) | catalogued as COSV66286552; called by muse, mutect2, varscan2
- IGKV4-1 | c.154A>C p.S52R | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs573464044; called by muse, mutect2, varscan2
- IL17RA | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1236554644, COSV60056659; called by muse, mutect2
- INTS3 | c.3022G>A p.E1008K | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.956); catalogued as rs759263034, COSV55162151; called by muse, mutect2
- KCND2 | c.299G>C p.R100P | Missense Mutation (SNP) | VAF 85/585 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58567964; called by muse, mutect2, varscan2
- KCNJ2 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 140/614 reads (23%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.984); catalogued as COSV99078943; called by muse, mutect2, varscan2
- KCNQ3 | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749205120, COSV101196319, COSV66465699; called by muse, mutect2, varscan2
- KLHL22 | c.1196G>T p.R399M | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV61023189; called by muse, mutect2, varscan2
- KRT18 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as rs746093574, COSV66316414; called by muse, mutect2
- KRT6C | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 59/562 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52880586; called by muse, varscan2
- LARP6 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs200378737; called by muse, mutect2
- LEFTY2 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV64747218; called by muse, mutect2, varscan2
- LIG1 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371317271; called by muse, mutect2
- LRCH2 | c.1454A>T p.Q485L | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as COSV100407149; called by muse, mutect2, varscan2
- LRFN5 | c.137C>A p.P46Q | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53269088; called by muse, mutect2, varscan2
- LRIF1 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs1557836438, COSV63896910; called by muse, mutect2
- LRRC7 | c.3205G>T p.D1069Y (on ENST00000651989 / NM_001370785.2; = p.D1036Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50435484; called by muse, mutect2, varscan2
- LRRIQ1 | c.4826T>C p.I1609T | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs759144142; called by muse, mutect2
- LSAMP | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 106/547 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100372744, COSV61300700; called by muse, varscan2
- LZTS2 | c.1994C>T p.T665I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as rs1007660297; called by muse, mutect2
- MAP7D1 | c.260del p.P87Lfs*46 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | catalogued as COSV60217294; called by mutect2, pindel, varscan2
- MGAM | c.2627C>T p.S876F | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1324062233, COSV72073981; called by muse, mutect2, varscan2
- MINAR1 | c.538G>T p.G180* | Nonsense Mutation (SNP) | VAF 43/152 reads (28%) | catalogued as rs538077419; called by muse, mutect2, varscan2
- MMUT | c.1885del p.R629Efs*19 | Frame Shift Del (DEL) | VAF 100/633 reads (16%) | catalogued as CM098910; called by mutect2, pindel, varscan2
- MPPED2 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as COSV63896588; called by muse, mutect2, varscan2
- MSH4 | c.1033C>G p.P345A | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs573895131; called by muse, mutect2, varscan2
- MYH7 | c.-8-1G>A | Splice Site (SNP) | VAF 23/251 reads (9%) | catalogued as rs1221287083; called by muse, mutect2, varscan2
- NADSYN1 | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs759644794; called by muse, mutect2, varscan2
- NBAT1 | n.156G>A | Splice Region (SNP) | VAF 40/246 reads (16%) | catalogued as rs1017977326; called by muse, mutect2, varscan2
- NDNF | c.347A>G p.Q116R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.628); catalogued as COSV104428392; called by mutect2, varscan2
- NDUFAF7 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 14/424 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50018955; called by muse, mutect2
- NF1 | c.3827G>T p.R1276L | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM000802, CM983421, COSV100648616, COSV62196628, COSV62224419; called by muse, mutect2, varscan2
- NF1 | c.4930G>C p.D1644H (on ENST00000358273 / NM_001042492.3; = p.D1623H on NM_000267.3) | Missense Mutation (SNP) | VAF 69/364 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131691123, CM143422, CM143423, CM1512957, COSV55986770, COSV99907744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFATC3 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs377286005; called by muse, mutect2, varscan2
- NOTCH3 | c.6395C>T p.A2132V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1300230282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPFFR2 | c.960C>G p.I320M | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58148156; called by muse, mutect2, varscan2
- NPHS1 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.208); catalogued as COSV62287677; called by muse, mutect2, varscan2
- OBSCN | c.3979G>A p.E1327K | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.905); catalogued as rs1163520971; called by muse, mutect2
- OR13A1 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV65572361; called by muse, mutect2
- OR14K1 | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.468); catalogued as COSV99315456; called by muse, varscan2
- OR2B11 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59511439; called by muse, mutect2, varscan2
- OR2F2 | c.907A>T p.K303* | Nonsense Mutation (SNP) | VAF 24/99 reads (24%) | catalogued as COSV68832646; called by muse, mutect2, varscan2
- OR2L3 | c.842C>G p.T281S | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63455992; called by muse, mutect2, varscan2
- OR3A2 | c.875C>A p.P292H | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68695250; called by muse, mutect2, varscan2
- OR4C11 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs773720877; called by muse, mutect2, varscan2
- OR51B2 | c.751G>T p.V251F | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV60917858; called by muse, mutect2, varscan2
- OR51M1 | c.273del p.T92Pfs*38 | Frame Shift Del (DEL) | VAF 39/236 reads (17%) | catalogued as rs747305645; called by mutect2, pindel, varscan2
- OR56A5 | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs764888953; called by muse, mutect2, varscan2
- OR5H6 | c.355del p.S119Pfs*3 (on ENST00000642105; = p.S103Pfs*3 on NM_001005479.2) | Frame Shift Del (DEL) | VAF 24/182 reads (13%) | catalogued as rs747281928; called by mutect2, varscan2
- OR5H6 | c.350T>A p.F117Y (on ENST00000642105; = p.F101Y on NM_001005479.2) | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as rs1240505612; called by mutect2, varscan2
- OR6T1 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100190197; called by muse, mutect2, varscan2
- OR8A1 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.379); catalogued as rs769868592, COSV52510235; called by muse, mutect2, varscan2
- OR8I2 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 58/226 reads (26%) | catalogued as COSV56168936; called by muse, mutect2, varscan2
- OTOGL | c.6085A>G p.N2029D (on ENST00000547103; = p.N2020D on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/289 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs758414118; called by muse, mutect2, varscan2
- OTOGL | c.6140G>A p.C2047Y (on ENST00000547103; = p.C2038Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100086681; called by muse, mutect2, varscan2
- OTUD6B | c.290G>C p.R97P | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs765027683; called by muse, mutect2, varscan2
- PACS1 | c.979-4A>G | Splice Region (SNP) | VAF 41/235 reads (17%) | catalogued as rs1353644429; called by muse, mutect2, varscan2
- PCDHB1 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV60629568; called by muse, mutect2, varscan2
- PCDHGB2 | c.1012C>T p.L338F | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV53917615; called by muse, mutect2
- PCP4 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs373116719, COSV60789485; called by muse, mutect2, varscan2
- PDZRN3 | c.908G>T p.R303M | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV55215897; called by muse, mutect2, varscan2
- PLCB1 | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV62054081; called by muse, mutect2, varscan2
- PMS2 | c.1905A>T p.E635D | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56222238; called by muse, mutect2, varscan2
- PPP1R2B | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 68/311 reads (22%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.789); catalogued as rs759460588; called by muse, mutect2, varscan2
- PRAMEF11 | c.702G>T p.R234S | Missense Mutation (SNP) | VAF 52/465 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs777137720; called by muse, mutect2, varscan2
- PRDM2 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV52454253; called by muse, mutect2, varscan2
- PRDM9 | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 123/1025 reads (12%) | catalogued as COSV99690943; called by muse, mutect2, varscan2
- PRSS37 | c.158C>A p.P53Q | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV63338975; called by muse, mutect2, varscan2
- PRSS55 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.035); catalogued as COSV100153806, COSV99073618; called by muse, mutect2, varscan2
- PTCHD4 | c.1304A>G p.H435R | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.757); catalogued as rs749249094; called by muse, mutect2, varscan2
- PTPRD | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 49/306 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV61985664; called by muse, mutect2, varscan2
- PTPRR | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 74/481 reads (15%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs748791402; called by muse, mutect2, varscan2
- PYHIN1 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100932337, COSV63722084, COSV63722655; called by muse, mutect2, varscan2
- RBBP6 | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100155062; called by muse, mutect2, varscan2
- RBP2 | c.155C>A p.T52K | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV51675009; called by muse, mutect2
- RGS18 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV66509318, COSV66509744; called by muse, mutect2, varscan2
- RYR2 | c.6077G>T p.R2026I | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99053456; called by muse, mutect2, varscan2
- S100A12 | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs113918672; called by muse, mutect2, varscan2
- SCN10A | c.2945A>G p.D982G | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs970548051; called by muse, mutect2, varscan2
- SDK2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs1463490457, COSV104428863; called by muse, mutect2, varscan2
- SEMA3A | c.1865G>C p.R622T | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs758249305; called by muse, mutect2, varscan2
- SEMA3G | c.830A>G p.Q277R | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs866971995; called by muse, mutect2, varscan2
- SERPINA3 | c.485del p.G162Afs*23 | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | catalogued as COSV67587171; called by mutect2, pindel, varscan2
- SERPINA4 | c.1055C>T p.T352I | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as rs1458918734; called by muse, mutect2
- SETDB1 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV54994047; called by muse, mutect2, varscan2
- SEZ6L | c.1952G>T p.G651V | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50670027; called by muse, mutect2, varscan2
- SGIP1 | c.1009C>A p.P337T | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs781666530; called by muse, mutect2, varscan2
- SHANK1 | c.4007G>T p.R1336L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs1005312231; called by muse, mutect2
- SIRPA | c.673C>A p.Q225K | Missense Mutation (SNP) | VAF 82/374 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV61539948; called by muse, mutect2, varscan2
- SLC16A7 | c.691del p.E231Kfs*7 | Frame Shift Del (DEL) | VAF 36/181 reads (20%) | catalogued as COSV53893030; called by mutect2, pindel, varscan2
- SLC30A3 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1162915438; called by muse, mutect2, varscan2
- SLC4A3 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as rs780597198; called by muse, mutect2, varscan2
- SLC9A4 | c.968C>A p.S323Y | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167931361, COSV99762709; called by muse, mutect2, varscan2
- SLITRK4 | c.1162A>G p.S388G | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs782093034; called by muse, mutect2, varscan2
- SPATA31D1 | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV100782386; called by muse, mutect2, varscan2
- SPATA31D1 | c.4174A>G p.I1392V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs376356216; called by muse, mutect2, varscan2
- SPTA1 | c.7083C>G p.F2361L | Missense Mutation (SNP) | VAF 115/497 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63753343; called by muse, mutect2, varscan2
- SRSF8 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 62/304 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.44); catalogued as rs782060682, COSV71665594; called by muse, mutect2, varscan2
- SSH2 | c.1786G>T p.D596Y | Missense Mutation (SNP) | VAF 72/479 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52180858; called by muse, mutect2, varscan2
- STAC3 | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 80/466 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761120163; called by muse, mutect2, varscan2
- SUCLG2 | c.111G>T p.W37C | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV56206793; called by muse, mutect2, varscan2
- SWT1 | c.2179G>T p.G727C | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV62259855; called by muse, mutect2, varscan2
- SYCP2L | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV51649438; called by muse, mutect2, varscan2
- TBC1D13 | c.945C>G p.F315L | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV99804299, COSV99804559; called by muse, mutect2
- TBX22 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV64784889; called by muse, mutect2, varscan2
- TH | c.1125C>A p.F375L (on ENST00000381178 / NM_199292.3; = p.F344L on NM_000360.4) | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as CM093636; called by muse, mutect2, varscan2
- THSD7B | c.2960-1G>T p.X987_splice | Splice Site (SNP) | VAF 22/88 reads (25%) | catalogued as COSV99742390, COSV99757302; called by muse, mutect2, varscan2
- TIGIT | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 79/404 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.086); catalogued as COSV67329267; called by muse, mutect2, varscan2
- TMPRSS15 | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV53038479; called by muse, mutect2
- TNN | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as rs758243448; called by muse, mutect2, varscan2
- TNRC6A | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs200041337, COSV59371280; called by muse, mutect2, varscan2
- TNRC6B | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57310355; called by muse, mutect2, varscan2
- TOPBP1 | c.4072G>C p.D1358H | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV99604939; called by muse, mutect2, varscan2
- TPRG1 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61469624; called by muse, mutect2, varscan2
- TRIM9 | c.1558G>T p.G520* | Nonsense Mutation (SNP) | VAF 45/290 reads (16%) | catalogued as COSV53617544; called by muse, mutect2, varscan2
- TTN | c.5848C>T p.H1950Y (on ENST00000591111; = p.H1904Y on NM_003319.4) | Missense Mutation (SNP) | VAF 21/464 reads (5%) | PolyPhen benign (0.058); catalogued as COSV100592767; called by muse, mutect2
- TUB | c.1205G>A p.R402H (on ENST00000299506 / NM_177972.3; = p.R457H on NM_003320.4) | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs754190421; called by muse, mutect2, varscan2
- TWIST1 | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as rs372098969; called by muse, varscan2
- UROC1 | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 42/259 reads (16%) | catalogued as COSV99331227; called by muse, mutect2, varscan2
- USH2A | c.14671G>T p.G4891W | Missense Mutation (SNP) | VAF 129/575 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56392263, COSV56393439; called by muse, mutect2, varscan2
- WNK3 | c.4210G>C p.E1404Q | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as rs1557150435; called by muse, mutect2, varscan2
- WSCD2 | c.1626C>A p.Y542* | Nonsense Mutation (SNP) | VAF 36/190 reads (19%) | catalogued as COSV54592323; called by muse, mutect2, varscan2
- ZBTB10 | c.997G>T p.G333W | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV66948018; called by muse, mutect2, varscan2
- ZBTB12 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs555290175, COSV64993558; called by muse, mutect2, varscan2
- ZFHX4 | c.7391C>T p.S2464L | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.56); catalogued as COSV50907517; called by muse, mutect2
- ZIM3 | c.599G>A p.C200Y | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149938645, COSV99517753; called by muse, mutect2, varscan2
- ZNF213 | c.252C>G p.I84M | Missense Mutation (SNP) | VAF 11/299 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1203431802, COSV101206060; called by muse, mutect2
- ZNF460 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV64416066; called by muse, mutect2, varscan2
- ZNF831 | c.2687G>T p.R896M | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV64046133; called by muse, varscan2
- ZRANB3 | c.3080G>T p.G1027V | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.384); catalogued as rs372611635; called by muse, mutect2, varscan2
- A2M | c.4220G>C p.R1407P | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA9 | c.3944G>C p.C1315S | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); called by muse, mutect2
- ABCB10 | c.1588G>T p.G530C | Missense Mutation (SNP) | VAF 73/317 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC10 | c.1795G>T p.E599* (on ENST00000372530 / NM_001198934.2; = p.E571* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/218 reads (18%) | called by muse, mutect2, varscan2
- ABCC8 | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- ACACB | c.2492A>T p.Q831L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- ADAM19 | c.2613G>T p.R871S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ADAM33 | c.1919G>T p.R640M | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- ADAMTS10 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS12 | c.2519G>T p.C840F | Missense Mutation (SNP) | VAF 95/185 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS16 | c.705C>A p.S235R | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY1 | c.1308-1G>A p.X436_splice | Splice Site (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- ADCY9 | c.2600G>T p.C867F | Missense Mutation (SNP) | VAF 54/341 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRE3 | c.1195C>G p.L399V | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRL4 | c.1953del p.S652Afs*38 | Frame Shift Del (DEL) | VAF 31/268 reads (12%) | called by mutect2, pindel, varscan2
- AGBL3 | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AGL | c.2545A>T p.R849* | Nonsense Mutation (SNP) | VAF 28/217 reads (13%) | called by muse, mutect2, varscan2
- AGRN | c.2081G>T p.W694L | Missense Mutation (SNP) | VAF 73/395 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AIRE | c.197T>G p.L66R | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP1 | c.1200dup p.D401Rfs*51 | Frame Shift Ins (INS) | VAF 22/132 reads (17%) | called by mutect2, pindel, varscan2
- ALDH7A1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.717); called by muse, mutect2
- ANK2 | c.256A>T p.R86* | Nonsense Mutation (SNP) | VAF 115/418 reads (28%) | called by muse, mutect2, varscan2
- ANKIB1 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 65/376 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANO10 | c.906G>T p.E302D | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AP3B1 | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- APOB | c.12946C>A p.Q4316K | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- APPBP2 | c.198dup p.A67Cfs*2 | Frame Shift Ins (INS) | VAF 41/303 reads (14%) | called by mutect2, pindel, varscan2
- ARHGAP9 | c.1847G>T p.R616L (on ENST00000393797 / NM_001319850.2; = p.R597L on NM_032496.4) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ARHGEF10L | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.036); called by muse, mutect2
- ARHGEF25 | c.1304G>C p.R435T | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2
- ATP8A2 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- B4GALT1 | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 26/363 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); called by muse, mutect2
- BCL9L | c.4123C>T p.P1375S | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.012); called by muse, mutect2
- BEND2 | c.1418C>A p.P473H | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4706G>T p.R1569M | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- BPNT2 | c.809-1G>T p.X270_splice | Splice Site (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- BSND | c.232A>T p.M78L | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1orf141 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- C1orf167 | c.1241C>A p.P414H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- C2orf88 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 74/299 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- CACNA1E | c.1984G>T p.V662L | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CACNA1E | c.6399G>C p.Q2133H (on ENST00000367573 / NM_001205293.3; = p.Q2090H on NM_000721.4) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- CACNA1S | c.2393C>G p.A798G | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CACNA1S | c.2392G>T p.A798S | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.056); called by mutect2, varscan2
- CACNA2D1 | c.2006A>G p.D669G (on ENST00000356253 / NM_001366867.1; = p.D657G on NM_000722.4) | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.093); called by muse, mutect2
- CALCRL | c.582C>A p.H194Q | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- CARMIL1 | c.3463G>T p.G1155W | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.928); called by muse, mutect2
- CASC3 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2
- CASP7 | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CBLB | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 20/371 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.212); called by muse, mutect2
- CBY3 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CCDC27 | c.712-2A>T p.X238_splice | Splice Site (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2
- CD1E | c.921T>A p.F307L | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD200 | c.259G>T p.V87L (on ENST00000473539 / NM_001004196.3; = p.V62L on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CDC42BPG | c.2638_2639del p.T880Afs*30 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by pindel, varscan2
- CDH10 | c.677A>T p.N226I | Missense Mutation (SNP) | VAF 72/764 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2
- CDHR3 | c.622G>T p.V208L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- CDK18 | c.575G>T p.R192L (on ENST00000506784 / NM_212503.3; = p.R162L on NM_002596.4) | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- CDK5RAP2 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CDKN2B | c.354C>A p.D118E | Missense Mutation (SNP) | VAF 59/393 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- CEP290 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- CEP350 | c.3218A>T p.Y1073F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, varscan2
- CFAP251 | c.1810G>T p.E604* | Nonsense Mutation (SNP) | VAF 59/439 reads (13%) | called by muse, mutect2, varscan2
- CFAP43 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2
- CFH | c.1448C>A p.T483K | Missense Mutation (SNP) | VAF 80/358 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, varscan2
- CHD5 | c.3415C>A p.Q1139K | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CHL1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.286); called by muse, mutect2
- CHRNB2 | c.1244G>T p.R415L | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CIT | c.1187G>T p.W396L | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN3 | c.509G>T p.S170I | Missense Mutation (SNP) | VAF 67/363 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- CNTNAP2 | c.1280C>A p.T427N | Missense Mutation (SNP) | VAF 130/484 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTNAP2 | c.1997G>T p.S666I | Missense Mutation (SNP) | VAF 74/617 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- COG5 | c.2037G>T p.L679F (on ENST00000347053 / NM_001379512.1; = p.L700F on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/392 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- COL4A6 | c.4881C>A p.D1627E | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- COL6A3 | c.5279A>T p.Q1760L | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- CPNE7 | c.1480A>T p.K494* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- CRLF1 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 21/141 reads (15%) | called by muse, mutect2, varscan2
- CSMD3 | c.9712del p.Q3238Rfs*34 (on ENST00000297405 / NM_001363185.1; = p.Q3069Rfs*34 on NM_052900.3) | Frame Shift Del (DEL) | VAF 44/391 reads (11%) | called by mutect2, pindel, varscan2
- CTNND2 | c.2938G>T p.A980S | Missense Mutation (SNP) | VAF 146/682 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.97); called by muse, varscan2
- CTNND2 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 28/500 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.214); called by muse, mutect2
- CTPS2 | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUBN | c.3673G>T p.V1225L | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CYP24A1 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 26/465 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.116); called by muse, mutect2
- DAB2 | c.575G>C p.G192A | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DCAF8L2 | c.1393G>T p.G465* | Nonsense Mutation (SNP) | VAF 49/140 reads (35%) | called by muse, mutect2, varscan2
- DCDC1 | c.1466C>G p.P489R | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DCHS1 | c.1276G>T p.V426L | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DDB1 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDR2 | c.2308G>T p.V770L | Missense Mutation (SNP) | VAF 156/749 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- DDX28 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DDX46 | c.1831G>C p.E611Q | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DISP2 | c.614C>A p.P205Q | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLEU7 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DLGAP2 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2
- DLGAP3 | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 44/406 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DMD | c.6312G>C p.E2104D | Missense Mutation (SNP) | VAF 79/210 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DMD | c.65C>A p.T22K | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- DNAH5 | c.9805A>G p.I3269V | Missense Mutation (SNP) | VAF 78/758 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DNAI4 | c.2180G>T p.W727L | Missense Mutation (SNP) | VAF 52/411 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAJC4 | c.725G>C p.*242Sext*28 | Nonstop Mutation (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- DOCK8 | c.634A>T p.N212Y | Missense Mutation (SNP) | VAF 99/514 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DRD2 | c.171G>T p.M57I | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DRD3 | c.178C>A p.L60M | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DROSHA | c.728G>C p.R243T | Missense Mutation (SNP) | VAF 35/315 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DSG3 | c.1068C>A p.H356Q | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP15 | c.431C>G p.A144G | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYSF | c.5663del p.K1888Rfs*78 | Frame Shift Del (DEL) | VAF 55/327 reads (17%) | called by mutect2, pindel, varscan2
- EBLN1 | c.997C>A p.P333T | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFTUD2 | c.1076_1077insT p.K359Nfs*5 | Frame Shift Ins (INS) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- EHHADH | c.1372A>T p.T458S | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- EIF5B | c.1291G>A p.V431I | Missense Mutation (SNP) | VAF 34/393 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.97); called by muse, mutect2
- EMCN | c.104C>A p.T35K | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ENTPD1 | c.773A>G p.K258R | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EOGT | c.1382G>T p.R461I (on ENST00000383701 / NM_001278689.2; = p.R377I on NM_173654.3) | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- EPB41 | c.1222G>T p.G408* (on ENST00000343067 / NM_001166005.2; = p.G199* on NM_004437.4) | Nonsense Mutation (SNP) | VAF 39/246 reads (16%) | called by muse, mutect2, varscan2
- ERICH3 | c.3824C>T p.A1275V | Missense Mutation (SNP) | VAF 47/361 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERICH3 | c.1847G>T p.R616I | Missense Mutation (SNP) | VAF 54/405 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ERVV-2 | c.1184A>T p.Q395L | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ESF1 | c.2548G>T p.V850F | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EXOC4 | c.370G>T p.V124F | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- EXT2 | c.1737G>C p.K579N (on ENST00000343631; = p.K612N on NM_000401.3) | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- F13B | c.557C>A p.T186K | Missense Mutation (SNP) | VAF 108/493 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM135A | c.844C>T p.R282* (on ENST00000370479 / NM_001351599.1; = p.R265* on NM_020819.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/147 reads (21%) | called by muse, mutect2, varscan2
- FAM171B | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- FAM209B | c.25G>T p.V9F | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FAM50A | c.560G>A p.W187* | Nonsense Mutation (SNP) | VAF 62/143 reads (43%) | called by muse, mutect2, varscan2
- FANCD2 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- FGB | c.1403T>A p.M468K | Missense Mutation (SNP) | VAF 114/501 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- FGD4 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 27/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGF14 | c.603G>T p.L201F | Missense Mutation (SNP) | VAF 42/372 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- FLG2 | c.5363C>A p.S1788Y | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- FLNB | c.548G>T p.C183F | Missense Mutation (SNP) | VAF 55/365 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLOT1 | c.56del p.S19Tfs*28 | Frame Shift Del (DEL) | VAF 29/142 reads (20%) | called by mutect2, varscan2
- FLOT1 | c.55A>T p.S19C | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by mutect2, varscan2
- FN1 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 117/407 reads (29%) | called by muse, mutect2, varscan2
- FOXI1 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FOXK1 | c.1738G>T p.A580S | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- FSIP2 | c.14843T>G p.F4948C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- GABRA2 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 42/394 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRG3 | c.1190G>T p.W397L | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GALC | c.274G>C p.G92R | Missense Mutation (SNP) | VAF 27/454 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GAS2 | c.241A>T p.S81C | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GAS8 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GCN1 | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GDAP2 | c.956A>G p.Y319C | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GDF3 | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- GDF7 | c.20C>A p.A7D | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- GFRA2 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 26/343 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2
- GIGYF2 | c.2563G>T p.E855* | Nonsense Mutation (SNP) | VAF 139/387 reads (36%) | called by muse, mutect2, varscan2
- GIPC2 | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GIPC2 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNAT3 | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 33/288 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- GPATCH8 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 70/370 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- GPR101 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- GPR101 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2
- GPR158 | c.2617G>T p.V873L | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- GPR158 | c.3637T>G p.F1213V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.018); called by muse, mutect2
- GREB1L | c.1664T>A p.V555E | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRM3 | c.801del p.N268Tfs*127 | Frame Shift Del (DEL) | VAF 62/228 reads (27%) | called by mutect2, pindel, varscan2
- GRM4 | c.277C>G p.R93G | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.05); called by muse, mutect2, varscan2
- GRM8 | c.2536G>T p.E846* | Nonsense Mutation (SNP) | VAF 71/422 reads (17%) | called by muse, mutect2, varscan2
- GRM8 | c.2137T>A p.W713R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRM8 | c.23del p.S8* | Frame Shift Del (DEL) | VAF 22/131 reads (17%) | called by mutect2, pindel, varscan2
- GTF3C1 | c.753-1G>C p.X251_splice | Splice Site (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- H3-3A | c.199C>G p.P67A | Missense Mutation (SNP) | VAF 7/202 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); called by muse, mutect2
- HABP4 | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 36/541 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.169); called by muse, mutect2
- HADH | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HEATR9 | c.1478C>A p.P493H | Missense Mutation (SNP) | VAF 72/397 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HINFP | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 14/121 reads (12%) | called by muse, mutect2, varscan2
- HIPK2 | c.1700C>G p.P567R | Missense Mutation (SNP) | VAF 69/366 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HNF1A | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HNF1A | c.1814dup p.N605Kfs*44 | Frame Shift Ins (INS) | VAF 121/590 reads (21%) | called by mutect2, pindel, varscan2
- HOOK2 | c.2126C>T p.A709V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- HRC | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.288); called by muse, mutect2
- HRH2 | c.245G>C p.C82S | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSCB | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HUWE1 | c.12328G>A p.V4110I | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- HUWE1 | c.7949G>T p.R2650L | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- IFT80 | c.712G>C p.A238P | Missense Mutation (SNP) | VAF 70/479 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- IGFBP3 | c.548G>T p.S183I | Missense Mutation (SNP) | VAF 81/446 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ILDR2 | c.667C>A p.P223T | Missense Mutation (SNP) | VAF 69/358 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- INPP5D | c.2806G>T p.D936Y (on ENST00000445964 / NM_001017915.3; = p.D935Y on NM_005541.5) | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- INSL4 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 75/337 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- INTS13 | c.1123C>G p.H375D | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- IPMK | c.1175G>T p.S392I | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IQCN | c.3236G>T p.R1079L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IRGC | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- IRGC | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ITGA2B | c.1571C>G p.A524G | Missense Mutation (SNP) | VAF 138/645 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ITGA4 | c.2257G>T p.E753* | Nonsense Mutation (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- ITGBL1 | c.467C>A p.T156K | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ITPK1 | c.84del p.E29Sfs*13 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | called by mutect2, pindel, varscan2
- ITPR2 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- JMJD1C | c.5689C>T p.H1897Y | Missense Mutation (SNP) | VAF 19/285 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- KANK1 | c.268del p.E90Nfs*19 | Frame Shift Del (DEL) | VAF 22/160 reads (14%) | called by mutect2, pindel, varscan2
- KATNBL1 | c.481A>T p.R161W | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KCNK2 | c.1232C>A p.T411K (on ENST00000444842 / NM_001017425.3; = p.T396K on NM_014217.4) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2
- KCNK5 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- KCNN3 | c.1472C>G p.S491C | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.537); called by muse, mutect2
- KCNV1 | c.1444C>A p.L482M | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KCTD3 | c.1325A>T p.N442I | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- KDM3B | c.2363A>G p.K788R | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDM5C | c.1695C>G p.H565Q | Missense Mutation (SNP) | VAF 95/210 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0232 | c.2570A>T p.N857I | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- KIF14 | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- KLHL14 | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KRTAP24-1 | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRTAP3-2 | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KSR1 | c.885G>T p.K295N (on ENST00000644974 / NM_001367810.1; = p.K158N on NM_014238.2) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LAMA2 | c.3952C>A p.P1318T | Missense Mutation (SNP) | VAF 103/459 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- LCE1F | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LDB2 | c.264C>G p.Y88* | Nonsense Mutation (SNP) | VAF 42/147 reads (29%) | called by muse, mutect2, varscan2
- LHFPL1 | c.21G>T p.M7I | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- LIPI | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LOXL2 | c.1285A>T p.M429L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.097); called by mutect2, varscan2
- LPO | c.-2-2A>T | Splice Site (SNP) | VAF 44/176 reads (25%) | called by muse, mutect2, varscan2
- LRCH2 | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- LRRC7 | c.1392G>T p.M464I (on ENST00000651989 / NM_001370785.2; = p.M431I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC7 | c.4118C>A p.S1373Y (on ENST00000651989 / NM_001370785.2; = p.S1293Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- MAGEA4 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- MAMLD1 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2
- MAP6 | c.1663G>A p.V555I | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MAST3 | c.1539G>T p.K513N | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- MATN2 | c.2723C>A p.P908H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MDN1 | c.12500C>A p.A4167E | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- MDN1 | c.4371G>T p.Q1457H | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MEGF11 | c.813C>A p.C271* | Nonsense Mutation (SNP) | VAF 45/186 reads (24%) | called by muse, mutect2, varscan2
- MEPE | c.1475G>T p.W492L | Missense Mutation (SNP) | VAF 50/267 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- MEPE | c.1476G>T p.W492C | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- MGA | c.3017del p.G1006Efs*16 | Frame Shift Del (DEL) | VAF 29/135 reads (21%) | called by mutect2, pindel, varscan2
- MGAM2 | c.4630A>G p.R1544G | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MIA2 | c.1774A>T p.T592S | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- MMP16 | c.1654del p.V552Sfs*11 | Frame Shift Del (DEL) | VAF 102/504 reads (20%) | called by mutect2, pindel, varscan2
- MOV10L1 | c.1466G>T p.R489L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- MPHOSPH9 | c.2173G>C p.E725Q | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.976); called by muse, mutect2
- MRC1 | c.4294A>C p.S1432R | Missense Mutation (SNP) | VAF 81/632 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- MRGPRE | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPL48 | c.113-2A>T p.X38_splice | Splice Site (SNP) | VAF 27/159 reads (17%) | called by muse, mutect2, varscan2
- MRTFB | c.2437C>G p.L813V (on ENST00000571589 / NM_001365412.2; = p.L763V on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MRTFB | c.2661G>T p.E887D (on ENST00000571589 / NM_001365412.2; = p.E837D on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- MSC | c.419A>T p.D140V | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSC-AS1 | n.342-3C>A | Splice Region (SNP) | VAF 51/183 reads (28%) | called by muse, mutect2, varscan2
- MUC16 | c.35020G>T p.V11674F | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MUC17 | c.8591C>A p.A2864D | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2
- MUC17 | c.12110C>A p.S4037Y | Missense Mutation (SNP) | VAF 67/293 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC4 | c.14783A>G p.N4928S (on ENST00000463781 / NM_018406.7; = p.N692S on NM_004532.6) | Missense Mutation (SNP) | VAF 15/460 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); called by muse, mutect2
- MYH1 | c.1950_1951delinsAGTC p.S652Cfs*9 | Frame Shift Ins (INS) | VAF 36/217 reads (17%) | called by pindel, varscan2*
- MYL7 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MYO16 | c.4448C>A p.P1483H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYRF | c.994C>A p.L332I (on ENST00000278836 / NM_001127392.3; = p.L323I on NM_013279.4) | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYRF | c.1707G>C p.E569D (on ENST00000278836 / NM_001127392.3; = p.E560D on NM_013279.4) | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- N4BP1 | c.2272G>T p.D758Y | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV2 | c.7054G>T p.D2352Y (on ENST00000396087 / NM_001244963.2; = p.D2293Y on NM_145117.5) | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- NBEAL1 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); called by muse, mutect2
- NCAPD3 | c.3398C>T p.P1133L | Missense Mutation (SNP) | VAF 97/423 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- NCAPD3 | c.1828C>T p.Q610* | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2
- NCOR2 | c.2091del p.V699Wfs*12 | Frame Shift Del (DEL) | VAF 28/214 reads (13%) | called by mutect2, pindel, varscan2
- NEB | c.14211+2T>A p.X4737_splice | Splice Site (SNP) | VAF 80/274 reads (29%) | called by muse, mutect2, varscan2
- NFATC4 | c.2258G>T p.G753V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NHEJ1 | c.829A>T p.T277S | Missense Mutation (SNP) | VAF 85/325 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP3 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 50/284 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- NMU | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 129/410 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- NOL8 | c.2588G>T p.G863V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOP56 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- NPIPB15 | c.97C>A p.R33S | Missense Mutation (SNP) | VAF 54/547 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- NR0B1 | c.251T>A p.L84Q | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRCAM | c.2162T>A p.V721E (on ENST00000379028 / NM_001371124.1; = p.V705E on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/359 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- NSD3 | c.1183A>C p.I395L | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NT5C3B | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- NTN1 | c.1147T>A p.C383S | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUB1 | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- NUP155 | c.3310A>T p.M1104L (on ENST00000231498 / NM_153485.3; = p.M1045L on NM_004298.4) | Missense Mutation (SNP) | VAF 62/592 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUP205 | c.1467A>T p.Q489H | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUSAP1 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OLAH | c.648C>A p.D216E (on ENST00000378228 / NM_001039702.3; = p.D269E on NM_018324.3) | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, mutect2
- OPTC | c.980C>A p.P327H | Missense Mutation (SNP) | VAF 64/364 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10C1 | c.289G>T p.G97* (on ENST00000622521; = p.G95* on NM_013941.3) | Nonsense Mutation (SNP) | VAF 48/291 reads (16%) | called by muse, mutect2, varscan2
- OR10G2 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OR1L8 | c.788C>A p.P263H | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR1N1 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- OR2AK2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR2D2 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- OR2M7 | c.197T>A p.L66Q | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2
- OR4A5 | c.897G>T p.L299F | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR4D11 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52B4 | c.440G>T p.C147F | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5AR1 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- OR5M10 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- OR6F1 | c.671C>A p.T224N | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- OR6F1 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR8J3 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OXCT1 | c.1209G>T p.Q403H | Missense Mutation (SNP) | VAF 89/591 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAN2 | c.2616C>G p.I872M (on ENST00000425394 / NM_001127460.3; = p.I868M on NM_014871.5) | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PAPOLB | c.1234A>G p.I412V | Missense Mutation (SNP) | VAF 61/299 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- PAPPA2 | c.3055G>T p.G1019W | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHB2 | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCDHGA2 | c.1352C>G p.A451G | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCNT | c.5358G>T p.Q1786H | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCNT | c.5359G>T p.A1787S | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PDE11A | c.2014G>T p.V672L | Missense Mutation (SNP) | VAF 114/432 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE1C | c.2077A>T p.R693W | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PDZK1 | c.1529C>G p.S510C | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PEX16 | c.647A>T p.Q216L | Missense Mutation (SNP) | VAF 21/303 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- PIF1 | c.1866+1G>T p.X622_splice | Splice Site (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- PIGC | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 40/272 reads (15%) | called by muse, mutect2, varscan2
- PIGM | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.42); called by muse, mutect2
- PIP5K1C | c.1662G>T p.Q554H | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PKP2 | c.1238G>T p.R413L | Missense Mutation (SNP) | VAF 64/400 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- PLAA | c.745A>T p.T249S | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PLB1 | c.3195+1G>C p.X1065_splice | Splice Site (SNP) | VAF 40/269 reads (15%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.1309-1G>A p.X437_splice (on ENST00000379409; = p.X385_splice on NM_032129.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- PLK3 | c.755C>G p.T252R | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLOD2 | c.1473G>T p.M491I | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- PLPPR5 | c.799G>T p.V267F | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PLPPR5 | c.799-1G>T p.X267_splice | Splice Site (SNP) | VAF 15/100 reads (15%) | called by muse, mutect2, varscan2
- PLVAP | c.65G>T p.W22L | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1536G>T p.M512I | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- POTEF | c.2297C>A p.T766N | Missense Mutation (SNP) | VAF 136/536 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- POU3F3 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- POU6F2 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 67/355 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PPFIA2 | c.2318C>A p.T773N | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PRDM14 | c.179C>A p.A60E | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PRKD1 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.206); called by muse, varscan2
- PRPF40B | c.878C>T p.P293L (on ENST00000380281; = p.P287L on NM_012272.3) | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PSG11 | c.465C>G p.N155K | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.173); called by muse, mutect2
- PSIP1 | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 58/372 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PSMC5 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 18/553 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- PTPRO | c.2105C>G p.S702* | Nonsense Mutation (SNP) | VAF 20/546 reads (4%) | called by muse, mutect2
- PTPRR | c.1313del p.N438Mfs*2 | Frame Shift Del (DEL) | VAF 15/156 reads (10%) | called by mutect2, pindel
- PTPRZ1 | c.2092G>T p.V698L | Missense Mutation (SNP) | VAF 104/327 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PXDN | c.4285T>A p.W1429R | Missense Mutation (SNP) | VAF 84/573 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PYROXD1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAB39B | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RANBP6 | c.2467A>T p.R823* | Nonsense Mutation (SNP) | VAF 23/154 reads (15%) | called by muse, mutect2, varscan2
- RAP1GDS1 | c.145G>T p.G49* (on ENST00000408927 / NM_001100427.2; = p.G50* on NM_021159.5) | Nonsense Mutation (SNP) | VAF 38/144 reads (26%) | called by muse, mutect2, varscan2
- RASA1 | c.200dup p.L67Ffs*45 | Frame Shift Ins (INS) | VAF 21/94 reads (22%) | called by mutect2, pindel, varscan2
- RASAL1 | c.1118G>T p.R373L | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RASEF | c.571G>T p.V191L | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- RAVER2 | c.1937C>A p.S646Y (on ENST00000294428 / NM_001366165.1; = p.S633Y on NM_018211.4) | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.174); called by muse, mutect2
- RCVRN | c.587A>G p.K196R | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- REG3A | c.282C>A p.S94R | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ROR2 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 48/526 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2
- RP1L1 | c.5594G>T p.G1865V | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- RSF1 | c.251C>A p.A84E | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- RSPO1 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 77/370 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- RXRG | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RYR1 | c.13468G>C p.E4490Q | Missense Mutation (SNP) | VAF 20/565 reads (4%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.782); called by muse, mutect2
- RYR2 | c.1153G>C p.G385R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RYR3 | c.11068A>C p.S3690R (on ENST00000389232; = p.S3691R on NM_001036.6) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- S100A7 | c.101C>A p.T34K | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SAMD9 | c.1415A>G p.Q472R | Missense Mutation (SNP) | VAF 50/362 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN8A | c.1864C>G p.Q622E | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SEMA3C | c.860G>T p.R287M | Missense Mutation (SNP) | VAF 48/352 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEPTIN10 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SETBP1 | c.3245C>A p.A1082D | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- SGCD | c.259C>A p.P87T (on ENST00000435422 / NM_001128209.2; = p.P88T on NM_000337.5) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- SH3KBP1 | c.321C>A p.F107L | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- SH3RF2 | c.269G>T p.R90M | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SHANK2 | c.2861G>C p.R954T | Missense Mutation (SNP) | VAF 16/440 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); called by muse, mutect2
- SI | c.4945G>T p.A1649S | Missense Mutation (SNP) | VAF 63/413 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SIPA1L2 | c.3175C>A p.P1059T | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SKOR1 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- SLC24A2 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 112/542 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2
- SLC30A10 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 102/445 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- SLC35F4 | c.95A>T p.Q32L | Missense Mutation (SNP) | VAF 52/466 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC3A1 | c.1552G>A p.G518S | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A15 | c.744G>T p.Q248H | Missense Mutation (SNP) | VAF 93/488 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SMARCC1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); called by muse, mutect2
- SMARCC2 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.932); called by muse, mutect2
- SNTB1 | c.937G>T p.G313W | Missense Mutation (SNP) | VAF 77/402 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- SORBS3 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SOX14 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SPAG4 | c.1305del p.H437Ifs*14 | Frame Shift Del (DEL) | VAF 22/117 reads (19%) | called by mutect2, pindel, varscan2
- SPHKAP | c.2249G>T p.S750I | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPINT3 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2
- SPO11 | c.548G>T p.R183I | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SRSF10 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 5/114 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2
- ST8SIA1 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- STK3 | c.89G>C p.G30A | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STK39 | c.1138G>C p.G380R | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STX19 | c.647A>T p.H216L | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STXBP5L | c.956+1G>T p.X319_splice | Splice Site (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- SULF1 | c.507T>A p.Y169* | Nonsense Mutation (SNP) | VAF 45/305 reads (15%) | called by muse, mutect2, varscan2
- SUSD1 | c.2092A>T p.T698S | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- SYAP1 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- SYT9 | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TARS1 | c.1661G>T p.R554L | Missense Mutation (SNP) | VAF 156/332 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- TBC1D32 | c.2245+1G>T p.X749_splice | Splice Site (SNP) | VAF 69/208 reads (33%) | called by muse, varscan2
- TCHH | c.2622G>T p.W874C | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- TCHHL1 | c.2659C>A p.H887N | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TDRD6 | c.1913A>G p.D638G | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TENT4A | c.2117A>G p.H706R | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.796); called by muse, mutect2
- TESPA1 | c.1063A>G p.T355A (on ENST00000316577 / NM_001098815.3; = p.T217A on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX15 | c.1354C>A p.Q452K (on ENST00000256246; = p.Q835K on NM_001350162.2) | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- TFAP2E | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- TFB1M | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 17/490 reads (3%) | called by muse, mutect2
- TG | c.7351G>T p.V2451L | Missense Mutation (SNP) | VAF 70/453 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TINAG | c.837G>T p.K279N | Missense Mutation (SNP) | VAF 65/395 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- TLR1 | c.1707C>A p.D569E | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TLR4 | c.1436C>G p.A479G (on ENST00000355622 / NM_138554.5; = p.A439G on NM_003266.4) | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- TMBIM6 | c.334A>T p.S112C | Missense Mutation (SNP) | VAF 87/410 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TMC3 | c.1825C>G p.Q609E | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- TMEM63C | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 80/380 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM63C | c.2220+2T>A p.X740_splice | Splice Site (SNP) | VAF 62/280 reads (22%) | called by muse, mutect2, varscan2
- TMF1 | c.2955_2963del p.I986_N988del | In Frame Del (DEL) | VAF 19/162 reads (12%) | called by mutect2, pindel, varscan2
- TNFSF10 | c.475A>T p.S159C | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- TNRC6C | c.3806G>T p.G1269V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- TNS1 | c.3287del p.G1096Efs*117 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | called by mutect2, pindel, varscan2
- TPK1 | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TRAF3IP2 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | called by muse, varscan2
- TRDV1 | c.188A>T p.K63I | Missense Mutation (SNP) | VAF 33/266 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRIM64B | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 42/476 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2
- TRPM6 | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 126/494 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPV5 | c.332C>A p.T111K | Missense Mutation (SNP) | VAF 98/366 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TSPOAP1 | c.4887C>G p.I1629M | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- TTN | c.69812C>T p.P23271L (on ENST00000591111; = p.P15847L on NM_003319.4) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUB | c.515G>T p.G172V (on ENST00000299506 / NM_177972.3; = p.G227V on NM_003320.4) | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- UBASH3A | c.1027G>C p.D343H | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE3B | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- UBE3B | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- UBE4B | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 88/470 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- UHRF1BP1L | c.351T>G p.F117L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, varscan2
- UNC13A | c.4318T>C p.S1440P | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- USH2A | c.4936G>T p.V1646F | Missense Mutation (SNP) | VAF 94/464 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- VARS1 | c.3401-2A>T p.X1134_splice | Splice Site (SNP) | VAF 39/137 reads (28%) | called by muse, mutect2, varscan2
- VPS8 | c.2098C>G p.L700V (on ENST00000625842 / NM_001349294.1; = p.L698V on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VWDE | c.3841C>A p.Q1281K | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDFY4 | c.1384G>T p.V462L | Missense Mutation (SNP) | VAF 40/364 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- WDPCP | c.694A>C p.N232H | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR75 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- WNK3 | c.3031G>C p.A1011P | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- WNT1 | c.409C>A p.H137N | Missense Mutation (SNP) | VAF 52/330 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- XRN2 | c.1401G>T p.Q467H | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- YARS2 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 80/448 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YME1L1 | c.872G>A p.R291K (on ENST00000326799 / NM_139312.3; = p.R234K on NM_014263.4) | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZFP41 | c.132_166del p.K45Rfs*6 | Frame Shift Del (DEL) | VAF 22/176 reads (13%) | called by mutect2, pindel
- ZFP90 | c.1799A>T p.Q600L | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- ZFPM2 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 62/393 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.76); called by muse, varscan2
- ZIC5 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZIM3 | c.600T>A p.C200* | Nonsense Mutation (SNP) | VAF 43/135 reads (32%) | called by muse, mutect2, varscan2
- ZNF112 | c.61G>T p.E21* (on ENST00000337401 / NM_001083335.2; = p.E15* on NM_013380.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 81/464 reads (17%) | called by muse, mutect2, varscan2
- ZNF14 | c.365T>G p.M122R | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- ZNF337 | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); called by muse, mutect2
- ZNF653 | c.1078G>C p.E360Q | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.777); called by muse, mutect2
- ZNF831 | c.2592G>T p.E864D | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, varscan2
- ZNF99 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); called by muse, mutect2
- ZP4 | c.544G>T p.G182* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2
- ABHD16A | c.408G>T p.R136= | Silent (SNP) | VAF 27/232 reads (12%) | called by muse, mutect2, varscan2
- ACCS | c.477C>T p.L159= | Silent (SNP) | VAF 14/229 reads (6%) | called by muse, mutect2
- ACLY | c.978C>G p.L326= | Silent (SNP) | VAF 8/240 reads (3%) | called by muse, mutect2
- ADAM20 | c.258C>T p.H86= | Silent (SNP) | VAF 58/272 reads (21%) | catalogued as rs1267724300; called by muse, mutect2, varscan2
- ADAM32 | c.804A>T p.L268= | Silent (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2
- ADAM8 | c.456C>T p.H152= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs775423816, COSV101291762; called by muse, mutect2
- ADAMTS12 | c.2520C>T p.C840= | Silent (SNP) | VAF 92/181 reads (51%) | catalogued as rs762596707, COSV100710024, COSV61281535; called by muse, mutect2, varscan2
- ADAMTS8 | c.1938C>A p.T646= | Silent (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- ADAMTSL5 | c.1212G>T p.R404= | Silent (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- ADCY8 | c.2877G>T p.V959= | Silent (SNP) | VAF 35/230 reads (15%) | called by muse, mutect2, varscan2
- ADH5 | c.687T>C p.F229= | Silent (SNP) | VAF 37/345 reads (11%) | catalogued as rs1332777946; called by muse, mutect2, varscan2
- AEBP2 | c.444C>T p.S148= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs779615599; called by mutect2, varscan2
- AHR | c.1524C>T p.I508= | Silent (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- AIRE | c.198G>T p.L66= | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- AKR7A2 | c.945G>T p.L315= | Silent (SNP) | VAF 51/415 reads (12%) | called by muse, mutect2, varscan2
- AMER3 | c.922A>C p.R308= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as COSV58469034; called by muse, mutect2, varscan2
- ANKRD12 | c.858T>C p.R286= | Silent (SNP) | VAF 17/342 reads (5%) | called by muse, mutect2
- ANO4 | c.285A>T p.P95= | Silent (SNP) | VAF 108/541 reads (20%) | called by muse, mutect2, varscan2
- AOAH | c.12C>A p.P4= | Silent (SNP) | VAF 65/224 reads (29%) | called by muse, mutect2, varscan2
- AQP12B | c.117G>A p.R39= | Silent (SNP) | VAF 281/547 reads (51%) | called by muse, mutect2, varscan2
- ARAP3 | c.2415A>G p.L805= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs982055034; called by muse, mutect2
- ARHGEF18 | c.1554G>T p.G518= (on ENST00000359920 / NM_001130955.2; = p.G414= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/203 reads (18%) | catalogued as COSV60473008; called by muse, mutect2, varscan2
- ASH1L | c.3780C>G p.L1260= | Silent (SNP) | VAF 24/337 reads (7%) | called by muse, mutect2
- ATP11C | c.747G>A p.L249= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV59564687; called by muse, mutect2, varscan2
- B3GALNT1 | c.54C>G p.L18= | Silent (SNP) | VAF 27/298 reads (9%) | called by muse, mutect2
- BCL11A | c.1191G>T p.S397= (on ENST00000335712 / NM_001365609.1; = p.S431= on NM_018014.4) | Silent (SNP) | VAF 103/410 reads (25%) | catalogued as rs1368637713; called by muse, mutect2, varscan2
- BRINP1 | c.462A>T p.S154= | Silent (SNP) | VAF 65/257 reads (25%) | called by muse, mutect2, varscan2
- BTN2A2 | c.126C>T p.P42= | Silent (SNP) | VAF 14/94 reads (15%) | called by muse, varscan2
- CACNA2D1 | c.1614A>G p.T538= | Silent (SNP) | VAF 21/209 reads (10%) | called by muse, mutect2, varscan2
- CACNG6 | c.441G>C p.L147= | Silent (SNP) | VAF 39/203 reads (19%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.1509A>T p.I503= (on ENST00000236925 / NM_001297707.2; = p.I492= on NM_203459.3) | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV52666745; called by muse, mutect2, varscan2
- CAMTA1 | c.3222C>A p.A1074= | Silent (SNP) | VAF 21/163 reads (13%) | called by muse, mutect2, varscan2
- CARD6 | c.1425C>G p.L475= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV54566899; called by muse, mutect2
- CCDC180 | c.2571G>T p.V857= | Silent (SNP) | VAF 24/306 reads (8%) | called by muse, mutect2
- CCNB3 | c.420C>G p.S140= | Silent (SNP) | VAF 51/122 reads (42%) | called by muse, mutect2, varscan2
- CD1B | c.718C>A p.R240= | Silent (SNP) | VAF 74/332 reads (22%) | catalogued as COSV100939203; called by muse, mutect2, varscan2
- CD200 | c.258T>A p.I86= (on ENST00000473539 / NM_001004196.3; = p.I61= on NM_005944.7 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 57/280 reads (20%) | called by muse, mutect2, varscan2
- CDC45 | c.1647G>A p.L549= | Silent (SNP) | VAF 161/315 reads (51%) | called by muse, mutect2, varscan2
- CEP170B | c.3346C>T p.L1116= (on ENST00000453495; = p.L1045= on NM_015005.3) | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs1383508623; called by muse, mutect2, varscan2
- CEP290 | c.3516A>G p.Q1172= | Silent (SNP) | VAF 26/190 reads (14%) | catalogued as rs1262065530; called by muse, mutect2, varscan2
- CEP95 | c.345C>T p.I115= | Silent (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- CFH | c.1449A>T p.T483= | Silent (SNP) | VAF 80/356 reads (22%) | called by muse, varscan2
- CHRNB2 | c.1245C>T p.R415= | Silent (SNP) | VAF 33/133 reads (25%) | called by muse, varscan2
- CNTN5 | c.258A>C p.S86= | Silent (SNP) | VAF 48/248 reads (19%) | called by muse, mutect2, varscan2
- COL18A1 | c.1822C>A p.R608= (on ENST00000359759 / NM_130444.3; = p.R373= on NM_030582.4) | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV62702989; called by muse, mutect2, varscan2
- COL4A1 | c.2646C>G p.G882= | Silent (SNP) | VAF 73/384 reads (19%) | catalogued as COSV101011278, COSV101011359; called by muse, mutect2, varscan2
- CR1L | c.183G>C p.L61= | Silent (SNP) | VAF 63/298 reads (21%) | catalogued as COSV99687884; called by muse, mutect2, varscan2
- CRISP3 | c.258C>A p.P86= (on ENST00000371159 / NM_001368123.1; = p.P68= on NM_006061.4) | Silent (SNP) | VAF 41/280 reads (15%) | catalogued as COSV53821653; called by muse, mutect2, varscan2
- CSMD2 | c.6873C>A p.L2291= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as rs571703956; called by muse, mutect2, varscan2
- CTTNBP2 | c.60G>A p.A20= | Silent (SNP) | VAF 62/165 reads (38%) | called by muse, mutect2, varscan2
- DAAM1 | c.234A>T p.P78= | Silent (SNP) | VAF 24/199 reads (12%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.666G>C p.G222= | Silent (SNP) | VAF 39/309 reads (13%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.546C>T p.I182= | Silent (SNP) | VAF 72/399 reads (18%) | catalogued as rs1213290899, COSV100151068, COSV60482036; called by muse, mutect2, varscan2
- DIXDC1 | c.774G>T p.G258= (on ENST00000440460 / NM_001037954.4; = p.G47= on NM_033425.4) | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV59460919; called by muse, mutect2, varscan2
- DNAH10 | c.7935A>G p.R2645= (on ENST00000409039; = p.R2584= on NM_207437.3) | Silent (SNP) | VAF 101/534 reads (19%) | catalogued as rs758024109; called by muse, mutect2, varscan2
- DNAJB13 | c.813G>A p.K271= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- DNASE1L3 | c.84C>T p.V28= | Silent (SNP) | VAF 39/267 reads (15%) | called by muse, mutect2, varscan2
- DOLK | c.900C>T p.L300= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV58280359; called by muse, mutect2, varscan2
- DVL1 | c.1323C>T p.I441= (on ENST00000378888 / NM_001330311.2; = p.I416= on NM_004421.3) | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as rs753509462; called by muse, mutect2, varscan2
- EFCAB6 | c.4491G>T p.R1497= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- EFCAB9 | c.432C>T p.L144= | Silent (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- EGF | c.1839C>T p.F613= | Silent (SNP) | VAF 59/261 reads (23%) | called by muse, mutect2, varscan2
- EHMT1 | c.39G>T p.G13= | Silent (SNP) | VAF 25/229 reads (11%) | called by muse, mutect2, varscan2
- EHMT2 | c.3357C>T p.I1119= | Silent (SNP) | VAF 56/288 reads (19%) | called by muse, mutect2, varscan2
- EML3 | c.1488C>A p.G496= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV99609955; called by muse, mutect2
- ETV3L | c.579T>C p.D193= | Silent (SNP) | VAF 46/235 reads (20%) | catalogued as rs756695296; called by muse, mutect2, varscan2
- ETV5 | c.285C>T p.P95= | Silent (SNP) | VAF 30/202 reads (15%) | called by muse, mutect2, varscan2
- EVC | c.1368G>T p.V456= | Silent (SNP) | VAF 90/356 reads (25%) | called by muse, mutect2, varscan2
- FASN | c.6240C>A p.V2080= | Silent (SNP) | VAF 22/178 reads (12%) | called by muse, mutect2
- FAT4 | c.10731G>A p.E3577= | Silent (SNP) | VAF 32/116 reads (28%) | called by muse, mutect2, varscan2
- FBXO42 | c.1962C>G p.T654= | Silent (SNP) | VAF 16/413 reads (4%) | called by muse, mutect2
- FBXO9 | c.240A>T p.A80= | Silent (SNP) | VAF 37/259 reads (14%) | called by muse, mutect2, varscan2
- FCRLA | c.84C>G p.A28= (on ENST00000367959; = p.A11= on NM_032738.4) | Silent (SNP) | VAF 24/119 reads (20%) | called by muse, mutect2, varscan2
- FGD5 | c.963C>G p.A321= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs373543905; called by muse, mutect2, varscan2
- FNBP4 | c.3027G>A p.K1009= | Silent (SNP) | VAF 18/302 reads (6%) | called by muse, mutect2
- FOXK1 | c.363C>T p.P121= | Silent (SNP) | VAF 14/220 reads (6%) | catalogued as rs1383337475; called by muse, mutect2
- FREM3 | c.4869T>A p.T1623= | Silent (SNP) | VAF 70/293 reads (24%) | called by muse, mutect2, varscan2
- FRS3 | c.399C>T p.A133= | Silent (SNP) | VAF 20/85 reads (24%) | called by muse, varscan2
- FYB1 | c.21G>T p.G7= | Silent (SNP) | VAF 40/317 reads (13%) | called by muse, mutect2, varscan2
- GALNT17 | c.186G>T p.A62= | Silent (SNP) | VAF 31/112 reads (28%) | called by muse, mutect2, varscan2
- GATA5 | c.832C>A p.R278= | Silent (SNP) | VAF 23/149 reads (15%) | catalogued as rs1200726928; called by muse, mutect2, varscan2
- GCNT1 | c.1011T>A p.P337= | Silent (SNP) | VAF 23/187 reads (12%) | called by muse, mutect2, varscan2
- GCNT2 | c.699C>T p.H233= | Silent (SNP) | VAF 33/155 reads (21%) | called by muse, mutect2, varscan2
- GJD3 | c.60C>G p.L20= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs373039837; called by muse, mutect2, varscan2
- GLRA4 | c.660C>A p.P220= | Silent (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- GNS | c.114C>T p.F38= | Silent (SNP) | VAF 15/201 reads (7%) | catalogued as rs1440511401; called by muse, mutect2
234 further variants in this file (0 protein-altering or splice-affecting, 126 silent, 108 other) are not listed here.
